Somatic mutation profile of tumor specimen TARGET-50-CAAAAA-01A (aliquot TARGET-50-CAAAAA-01A-01D) from TARGET case TARGET-50-CAAAAA, project TARGET-WT (High-Risk Wilms Tumor). Primary diagnosis: Wilms tumor; Tissue or organ of origin: Kidney, NOS.
Specimen TARGET-50-CAAAAA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 68453b42-90b0-4344-8ec1-6888ee75b594.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-50-CAAAAA-10A (Blood Derived Normal), aliquot TARGET-50-CAAAAA-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/026ece04-6b6d-4742-bf1a-64ad17c1e6cd

The open-access MAF lists 6 somatic variants for this specimen: 6 protein-altering or splice-affecting.
By variant classification: Missense Mutation 6.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CLN3 | c.1212G>C p.L404F (on ENST00000360019 / NM_001286104.2; = p.L428F on NM_000086.2) | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.211); catalogued as COSV61107752; called by muse, mutect2, varscan2
- HOGA1 | c.395C>T p.A132V | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.112); catalogued as rs200236086, COSV65706793; called by muse, mutect2, varscan2
- MLLT1 | c.1174G>C p.E392Q | Missense Mutation (SNP) | VAF 27/37 reads (73%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.989); catalogued as rs984051551, COSV53133074; called by muse, mutect2, varscan2
- SLC38A5 | c.188G>C p.G63A | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV58335206; called by muse, mutect2
- SUGCT | c.779G>C p.R260P | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59335604, COSV59353420; called by muse, mutect2, varscan2
- RNF8 | c.143A>G p.Y48C | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
